FM case AD5410 — Foundation Medicine Adult Cancer Clinical Dataset (FM-AD)
Open-access clinical record from the NCI Genomic Data Commons (Data Release 46.0 - August 10, 2026). Disease type: Adenomas and Adenocarcinomas; Primary site: Stomach.
https://portal.gdc.cancer.gov/cases/8948a932-75ce-4b2c-a9d3-3c43479d6bac

Male, 52.6 years: Adenocarcinoma, NOS (ICD-O-3 8140/3) of the small intestine; primary biopsied or resected from the small intestine. Tumor nuclei on the sequenced sample's slide: 20% (pathologist estimate recorded by GDC). Sample type: Primary Tumor.
